Somatic mutation profile of tumor specimen 0DEA0P from CCDI case PBBPKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 2.5 years (899 days).
Specimen 0DEA0P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 357bdd2b-2154-42cd-9214-6221d5173488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEA0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8278a9-7140-40a7-a921-3aa567581ce6

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF850 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs879154168; called by muse, mutect2
- PLEKHB2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 64/904 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- PKD1L3 | c.2220C>T p.S740= | Silent (SNP) | VAF 240/616 reads (39%) | catalogued as rs372942015, COSV58661820; called by muse, mutect2, varscan2
